Somatic mutation profile of tumor specimen TCGA-A2-A3XW-01A (aliquot TCGA-A2-A3XW-01A-11D-A23C-09) from TCGA case TCGA-A2-A3XW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 42.9 years (15,670 days).
Specimen TCGA-A2-A3XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78192f60-a160-41e0-b848-cbf13c1301d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A3XW-10A (Blood Derived Normal), aliquot TCGA-A2-A3XW-10A-01D-A23C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be76169-de89-4025-8dc9-a3b41ac7e27a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPSF1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs782689559, COSV100574731; called by muse, mutect2
- PHKB | c.2435T>C p.L812P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54532465; called by muse, mutect2
- ZC3H18 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99964379; called by muse, mutect2
- CRTAC1 | c.1779T>C p.S593= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV54008904; called by muse, mutect2, varscan2
- SSX5 | c.525G>A p.V175= (on ENST00000347757 / NM_175723.1; = p.V216= on NM_021015.4) | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- ZFHX4 | c.2334C>T p.V778= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs937285124, COSV50515055, COSV50723610; called by muse, mutect2, varscan2
